Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZH, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZH-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DOB:

Physician:

Accession:

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) RULE OUT PARATHYROID:

Thyroid tissue and adjacent soft tissue, no tumor present.

(B) TOTAL THYROIDECTOMY:

PAPILLARY THYROID CARCINOMA, 2.5 CM IN LEFT LOBE CONFINED TO GLAND.

TUMOR PRESENT WITHIN 1.0 MM OF MARGINS.

No tumor present in two perithyroidal lymph nodes.

FOCUS OF PAPILLARY THYROID CARCINOMA PRESENT IN SOFT TISSUE.

(C) LEFT SUPERIOR PARATRACHEAL TISSUE:

Thyroid tissue, no tumor present.

(D) LEFT PARATRACHEAL DISSECTION:

METASTATIC PAPILLARY THYROID CARCINOMA IN FOUR OF SIX LYMPH NODES (4/6), NO EXTRACAPSULAR EXTENSION.

Entire report and diagnosis completed by

ICD-0-3
carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS C73.9
lw
6/17/12

GROSS DESCRIPTION

(A) RULE OUT PARATHYROID - A 0.2 x 0.2 x 0.2 cm red-tan soft tissue fragment. Touch preps are performed and the specimen is entirely for frozen section as A.

*FS/DX: THYROID TISSUE AND ADJACENT SOFT TISSUE.

(B) TOTAL THYROIDECTOMY, STITCH MARK, RIGHT SUPERIOR POLE - A total thyroidectomy specimen consisting of a right lobe (7.0 x 3.5 x 2.5 cm), isthmus (1.0 x 1.0 cm) and left lobe (5.2 x 2.7 x 1.5 cm). The left lobe of thyroid reveals a 2.5 x 2.0 x 1.1 cm firm white-tan nodule in the superior third. The right lobe of thyroid has two nodules, a superior (0.7 x 0.6 x 0.5 cm) and inferior nodule (2.2 x 1.9 x 1.0 cm). Both the right lobe nodules are gelatinous tan-white.

Portions of the normal thyroid and nodules are submitted to the tumor bank.

SECTION CODE: B1-B9, left lobe, superior to inferior (nodule in B1-B4); B10, isthmus; B11-B15, right lobe, superior to inferior (superior third nodule in B11, inferior third nodule in B14, B15).

(C) LEFT SUPERIOR PARATRACHEAL TISSUE - A tan-pink nonoriented irregular fragment of tissue (0.6 x 0.4 x 0.3 cm). Toto in C.

(D) LEFT PARATRACHEAL DISSECTION - An irregular fragment of fibroadipose tissue (4.0 x 2.0 x 0.5 cm). The specimen is serially sectioned. Six lymph nodes are identified ranging from 0.3 x 0.2 x 0.2 to 0.5 x 0.5 x 0.4 cm.

SECTION CODE: D1, four lymph nodes; D2, two lymph nodes.

CLINICAL HISTORY

[page 2 of 2]
Surgical Pathology Report

Department of Pathology,

DOB
Physician:

Collected

Pathologist:

Accession:

Received:

Case type: Surgical Case

None given.

SNOMED CODES

T-B6000, M-80503

"Some tests reported here may have been developed and performance characteristics determined by I
by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or approved

Released by:

Surgical Pathology Report		Page 2 of 2
File under: Pathology		

Source: NCI Genomic Data Commons file f9fc1473-9219-455c-9c96-bae1f90ea4be (TCGA-EL-A3ZH.173A9ED2-E1E5-4EF7-A3B2-EA9E9F72422B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).